Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A438, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A438-01A (Primary Tumor).

[page 1 of 2]
Procurement Date: Laterality: N/A

Path Report: Left lobe of thyroid, partial thyroidectomy:

- Histologic type: Papillary thyroid carcinoma, no special type.

- Tumor size: 2.3 cm (greatest dimension)

- Location: left lobe

- Multicentricity: Absent

- Extent of invasion:

- Capsular invasion: Absent

- Angiolymphatic invasion: Absent

- Extra-thyroid capsular extension: Absent

- Invasion of tissue adjacent to thyroid: Absent

- Margins: Negative

- Lymph nodes: No evidence of malignancy (Positive/Total): (0/3) (present in specimens A, B and D).

- Uninvolved gland: Unremarkable

- Parathyroid tissue: Present 4 fragments of parathyroid tissue are present in slides A4, A5, C1, C2.

- Correlation with FNA/cytology: Correlates with prior FNA diagnosis of suspicious for papillary carcinoma.

ICD-O-3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9

8-3-12 RD

6/3/12

[page 2 of 2]
-
- Capsular invasion: Absent
- Angiolymphatic invasion: Absent
- Extra-thyroid capsular extension: Absent
- Invasion of tissue adjacent to thyroid: Absent
- Margins: Negative
- Lymph nodes: No evidence of malignancy (Positive/Total): (0/3) (present in specimens A, B and D).
- Uninvolved gland: Unremarkable
- Parathyroid tissue: Present 4 fragments of parathyroid tissue are present in slides A4, A5, C1, C2.
- Correlation with FNA/cytology: Correlates with prior FNA diagnosis of suspicious for papillary carcinoma.

Source: NCI Genomic Data Commons file 2428fe20-fb7b-4279-9f0a-0d97111cd61b (TCGA-E8-A438.F5A6C80F-594B-4FD3-9B9F-E0AB0D7F7EDE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).